Somatic mutation profile of tumor specimen TCGA-CQ-5325-01A (aliquot TCGA-CQ-5325-01A-01D-1683-08) from TCGA case TCGA-CQ-5325, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 65.3 years (23,833 days).
Specimen TCGA-CQ-5325-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aa1b0e32-5fd5-4b50-936f-e518d8f6f3db.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CQ-5325-10A (Blood Derived Normal), aliquot TCGA-CQ-5325-10A-01D-1683-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fa4624aa-59ec-4699-a638-188f86d18b5d

The open-access MAF lists 53 somatic variants for this specimen: 40 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 12, Nonsense Mutation 2, Splice Site 1, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM2 | c.428T>G p.V143G | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV99697489; called by muse, mutect2, varscan2
- AKAP12 | c.2266G>A p.V756I | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.887); catalogued as rs758119251, COSV53578472; called by muse, mutect2
- ALPK2 | c.2437G>A p.G813R | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.042); catalogued as COSV64497803; called by muse, mutect2, varscan2
- C1orf94 | c.1058T>C p.F353S (on ENST00000488417 / NM_001134734.2; = p.F163S on NM_032884.5) | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as COSV100975003; called by muse, mutect2
- C5orf22 | c.836A>G p.Y279C | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100323518; called by muse, mutect2
- CARD10 | c.269A>T p.K90M | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99325046; called by muse, mutect2
- CCNB1IP1 | c.638A>G p.N213S | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0); catalogued as COSV100738592; called by muse, mutect2
- CD2AP | c.1211C>T p.S404F | Missense Mutation (SNP) | VAF 23/190 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.305); catalogued as COSV100830465; called by muse, mutect2, varscan2
- CDK2AP2 | c.290G>A p.S97N | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as COSV100039419; called by muse, mutect2, varscan2
- CDKN1B | c.242A>G p.K81R | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV99963968; called by muse, mutect2
- CORO1C | c.723C>G p.S241R | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99776001; called by muse, mutect2, varscan2
- EPHX2 | c.869C>A p.A290D | Missense Mutation (SNP) | VAF 24/238 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV100994616; called by muse, mutect2, varscan2
- ETNPPL | c.1172+2T>G p.X391_splice | Splice Site (SNP) | VAF 22/289 reads (8%) | catalogued as COSV99625306; called by muse, mutect2
- GALNT13 | c.1153C>T p.P385S | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.206); catalogued as COSV101223250; called by muse, mutect2
- GIGYF2 | c.1756A>T p.M586L | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV101004422; called by muse, mutect2
- HERPUD1 | c.710A>T p.N237I | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100295966; called by muse, mutect2, varscan2
- HSD17B3 | c.848C>A p.A283D | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV100931277; called by muse, mutect2
- IDE | c.963C>G p.D321E | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99794065; called by muse, mutect2
- MAGEE1 | c.611C>T p.P204L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as rs1218815011, COSV100819423, COSV63910253; called by muse, mutect2
- OAS1 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.172); catalogued as COSV99177186; called by muse, mutect2
- PABPC5 | c.625G>A p.D209N | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV57042959; called by muse, mutect2, varscan2
- PCDHA7 | c.1078C>A p.P360T | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.334); catalogued as COSV100971544, COSV65346583; called by muse, mutect2, varscan2
- PLD3 | c.43G>T p.E15* | Nonsense Mutation (SNP) | VAF 10/117 reads (9%) | catalogued as COSV100735204; called by muse, mutect2
- POP5 | c.435C>A p.S145R | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.133); catalogued as COSV100378739; called by muse, mutect2
- PPP1R13L | c.1508C>T p.S503L | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs577151019, COSV100714789; called by muse, mutect2, varscan2
- RIPOR3 | c.2717C>A p.A906D | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99246630; called by muse, mutect2, varscan2
- RRM2B | c.409A>T p.M137L | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.232); catalogued as COSV99310229; called by muse, mutect2, varscan2
- SLC26A9 | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs747519882, COSV100536447; called by muse, mutect2, varscan2
- SLC2A9 | c.403C>A p.L135I | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.072); catalogued as rs200013912, COSV99304779; called by muse, mutect2, varscan2
- SULF1 | c.361C>T p.H121Y | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV99483282; called by muse, mutect2, varscan2
- TKFC | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.026); catalogued as COSV100074647; called by muse, mutect2, varscan2
- TNS4 | c.1960A>T p.M654L | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV99563898; called by muse, mutect2, varscan2
- VIL1 | c.1629T>G p.N543K | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99945608; called by muse, mutect2, varscan2
- WWOX | c.1052C>A p.S351Y | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV101283087; called by muse, mutect2
- XIRP2 | c.375G>C p.K125N | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.157); catalogued as COSV54703313, COSV99743898; called by muse, mutect2, varscan2
- XRCC2 | c.316G>T p.E106* | Nonsense Mutation (SNP) | VAF 10/92 reads (11%) | catalogued as COSV100831651; called by muse, mutect2, varscan2
- ZFHX4 | c.6676A>G p.K2226E | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as rs777773349, COSV51009410, COSV99263781; called by muse, mutect2
- ZNF276 | c.854C>T p.T285I (on ENST00000443381 / NM_001113525.2; = p.T210I on NM_152287.4) | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV99235035; called by muse, mutect2
- ZW10 | c.1812A>T p.L604F | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99562724; called by muse, mutect2, varscan2
- PSIP1 | c.358del p.E120Kfs*14 | Frame Shift Del (DEL) | VAF 15/130 reads (12%) | called by mutect2, pindel, varscan2
- CCKBR | c.180T>G p.L60= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as COSV100582974; called by muse, mutect2
- CLOCK | c.1317A>G p.K439= | Silent (SNP) | VAF 5/56 reads (9%) | catalogued as COSV100011835; called by muse, mutect2
- COL17A1 | c.957C>T p.N319= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV100793198, COSV100793465; called by muse, mutect2, varscan2
- DMD | c.6778T>C p.L2260= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as rs1176525732, COSV100627717; called by muse, mutect2, varscan2
- DOCK4 | c.5655G>A p.P1885= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as rs778923450, COSV70235253; called by muse, mutect2
- FCN3 | c.444C>T p.S148= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as COSV99585382; called by muse, mutect2, varscan2
- FUT10 | c.243C>T p.Y81= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs993677032, COSV100161509; called by muse, mutect2
- LMNTD1 | c.1078T>C p.L360= | Silent (SNP) | VAF 6/88 reads (7%) | catalogued as COSV99279887; called by muse, mutect2
- NAV3 | c.5466C>A p.L1822= (on ENST00000397909 / NM_001024383.2; = p.L1800= on NM_014903.6) | Silent (SNP) | VAF 10/91 reads (11%) | catalogued as COSV99891982; called by muse, mutect2
- PITPNM2 | c.2439A>G p.Q813= | Silent (SNP) | VAF 3/38 reads (8%) | catalogued as COSV99759147; called by muse, mutect2
- RGS20 | c.123C>T p.I41= | Silent (SNP) | VAF 14/100 reads (14%) | catalogued as COSV99809669; called by muse, mutect2, varscan2
- TPD52L3 | c.12C>G p.A4= | Silent (SNP) | VAF 70/176 reads (40%) | catalogued as COSV100096024; called by muse, mutect2, varscan2
- TRAC | c.*152A>T | 3'UTR (SNP) | VAF 20/171 reads (12%) | called by muse, mutect2, varscan2
